Somatic mutation profile of tumor specimen TCGA-99-8028-01A (aliquot TCGA-99-8028-01A-11D-2238-08) from TCGA case TCGA-99-8028, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 50.8 years (18,542 days).
Specimen TCGA-99-8028-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 48330638-0c8a-4ddd-81fc-7ed215d1869b.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-99-8028-10A (Blood Derived Normal), aliquot TCGA-99-8028-10A-01D-2238-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/76fb3ed7-96c6-497f-8a8b-3253c0d2f3da

The open-access MAF lists 405 somatic variants for this specimen: 309 protein-altering or splice-affecting, 92 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 263, Silent 92, Splice Site 19, Nonsense Mutation 19, Frame Shift Del 3, Intron 2, Translation Start Site 2, Splice Region 1, Nonstop Mutation 1, Frame Shift Ins 1, 5'Flank 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.34G>T p.G12C | Missense Mutation (SNP) | VAF 14/64 reads (22%) | hotspot (GDC flag); SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as rs121913530, CM076251, COSV55497461, COSV55497469, COSV55497582, COSV56157736; ClinVar: pathogenic / likely pathogenic / not provided; called by muse, mutect2, varscan2
- TP53 | c.725G>T p.C242F | Missense Mutation (SNP) | VAF 17/120 reads (14%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs121912655, CM910618, COSV52661189, COSV52677418, COSV52689710; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2, varscan2
- TTC21B | c.1999C>T p.Q667* | Nonsense Mutation (SNP) | VAF 38/334 reads (11%) | catalogued as rs1559056633, COSV54630022; ClinVar: pathogenic; called by muse, mutect2, varscan2
- AAAS | c.118G>T p.G40C | Missense Mutation (SNP) | VAF 14/262 reads (5%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.766); catalogued as COSV52932841; called by muse, mutect2
- ABCB11 | c.2608G>T p.G870W | Missense Mutation (SNP) | VAF 50/427 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV55589538; called by muse, mutect2, varscan2
- ABCB7 | c.441G>T p.L147F (on ENST00000373394 / NM_001271696.3; = p.L148F on NM_004299.6) | Missense Mutation (SNP) | VAF 18/263 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV53719504; called by muse, mutect2
- ABCC11 | c.3878T>C p.L1293P | Missense Mutation (SNP) | VAF 13/250 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV62322780; called by muse, mutect2
- ABCG1 | c.944G>T p.C315F | Missense Mutation (SNP) | VAF 18/329 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV59203577; called by muse, mutect2
- ACE | c.3421G>A p.A1141T | Missense Mutation (SNP) | VAF 19/196 reads (10%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.982); catalogued as COSV52006302; called by muse, mutect2, varscan2
- ACVR2B | c.264G>T p.Q88H | Missense Mutation (SNP) | VAF 38/476 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.062); catalogued as COSV100754463, COSV61702159; called by muse, mutect2
- ADAM29 | c.393C>A p.D131E | Missense Mutation (SNP) | VAF 10/146 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.528); catalogued as COSV63663133; called by muse, mutect2
- ADCY5 | c.1605C>A p.H535Q | Missense Mutation (SNP) | VAF 6/88 reads (7%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.545); catalogued as COSV59197140; called by muse, mutect2
- AFF2 | c.3640G>T p.V1214L | Missense Mutation (SNP) | VAF 16/234 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV53987137; called by muse, mutect2
- AHR | c.2026A>G p.T676A | Missense Mutation (SNP) | VAF 31/288 reads (11%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV54123194; called by muse, mutect2
- AIG1 | c.674A>T p.Q225L | Missense Mutation (SNP) | VAF 7/108 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.01); catalogued as COSV51625580; called by muse, mutect2
- AL121899.2 | c.1876G>T p.V626L | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.005); catalogued as COSV67350459; called by muse, mutect2
- ALOX12B | c.1531A>T p.K511* | Nonsense Mutation (SNP) | VAF 14/109 reads (13%) | catalogued as COSV59872484; called by muse, mutect2, varscan2
- ANK2 | c.10035G>T p.K3345N | Missense Mutation (SNP) | VAF 16/171 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.856); catalogued as COSV52158420; called by muse, mutect2
- ANKK1 | c.283G>C p.G95R | Missense Mutation (SNP) | VAF 6/49 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV58271572, COSV58272294; called by muse, mutect2, varscan2
- ANKS1B | c.274G>T p.G92W | Missense Mutation (SNP) | VAF 7/135 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61348617, COSV61383429; called by muse, mutect2
- ARHGAP12 | c.2458G>T p.G820C | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.156); catalogued as COSV60962952; called by mutect2, varscan2
- ARHGEF19 | c.1945G>C p.A649P | Missense Mutation (SNP) | VAF 9/154 reads (6%) | SIFT tolerated (0.28); PolyPhen benign (0.007); catalogued as COSV54616387, COSV54617374; called by muse, mutect2
- ARMH3 | c.326G>T p.R109L | Missense Mutation (SNP) | VAF 17/158 reads (11%) | SIFT tolerated (0.13); PolyPhen benign (0.243); catalogued as COSV100228878; called by muse, mutect2, varscan2
- ASTL | c.590C>A p.A197D | Missense Mutation (SNP) | VAF 13/152 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV60904098; called by muse, mutect2
- ATG4C | c.861A>T p.K287N | Missense Mutation (SNP) | VAF 10/138 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as COSV58605395; called by muse, mutect2
- ATP2B3 | c.209-2A>T p.X70_splice | Splice Site (SNP) | VAF 10/134 reads (7%) | catalogued as COSV54845621; called by muse, mutect2
- ATP4A | c.655G>C p.A219P | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.702); catalogued as COSV52867559; called by muse, mutect2
- BNIP5 | c.1860C>G p.C620W | Missense Mutation (SNP) | VAF 12/203 reads (6%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.735); catalogued as COSV71325513; called by muse, mutect2
- BOD1L1 | c.8050G>T p.G2684C | Missense Mutation (SNP) | VAF 21/364 reads (6%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.007); catalogued as COSV50011172; called by muse, mutect2
- BRINP1 | c.1738G>A p.G580R | Missense Mutation (SNP) | VAF 12/129 reads (9%) | SIFT tolerated (0.07); PolyPhen benign (0.435); catalogued as rs1039853087, COSV56298431; called by muse, mutect2
- C1orf131 | c.185T>C p.V62A | Missense Mutation (SNP) | VAF 6/92 reads (7%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs1179175515, COSV59642215, COSV59642695; called by muse, mutect2
- C4orf17 | c.721G>T p.A241S | Missense Mutation (SNP) | VAF 10/222 reads (5%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV58512232, COSV58513869; called by muse, mutect2
- CACNA1C | c.755C>A p.P252Q | Missense Mutation (SNP) | VAF 38/590 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV59713274; called by muse, mutect2
- CACNG6 | c.771C>A p.H257Q (on ENST00000252729 / NM_145814.1; = p.H186Q on NM_031897.2) | Missense Mutation (SNP) | VAF 38/223 reads (17%) | SIFT tolerated, low confidence (0.69); PolyPhen benign (0); catalogued as COSV53166507; called by muse, mutect2, varscan2
- CALCRL | c.1312A>G p.S438G | Missense Mutation (SNP) | VAF 15/89 reads (17%) | SIFT tolerated (0.11); PolyPhen benign (0.003); catalogued as rs780062941, COSV66474637; called by muse, mutect2, varscan2
- CAMSAP1 | c.4299A>G p.I1433M | Missense Mutation (SNP) | VAF 8/178 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.009); catalogued as COSV56721775; called by muse, mutect2
- CAPN13 | c.1372G>T p.V458L | Missense Mutation (SNP) | VAF 40/480 reads (8%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.589); catalogued as COSV54430115; called by muse, mutect2
- CAPNS1 | c.441G>T p.M147I | Missense Mutation (SNP) | VAF 33/332 reads (10%) | SIFT tolerated (0.13); PolyPhen benign (0.107); catalogued as COSV55822710; called by muse, mutect2, varscan2
- CCDC39 | c.1801G>T p.E601* | Nonsense Mutation (SNP) | VAF 8/157 reads (5%) | catalogued as COSV56483024; called by muse, mutect2
- CCT5 | c.28G>C p.D10H | Missense Mutation (SNP) | VAF 6/108 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.976); catalogued as COSV54723667; called by muse, mutect2
- CD180 | c.1312C>A p.Q438K | Missense Mutation (SNP) | VAF 28/254 reads (11%) | SIFT deleterious (0.02); PolyPhen benign (0.033); catalogued as COSV56517779; called by muse, mutect2
- CDAN1 | c.1368-1G>T p.X456_splice | Splice Site (SNP) | VAF 8/116 reads (7%) | catalogued as COSV62331782; called by muse, mutect2
- CDH13 | c.1600G>C p.D534H | Missense Mutation (SNP) | VAF 12/238 reads (5%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.69); catalogued as COSV51814114; called by muse, mutect2
- CDH8 | c.1711G>T p.V571F | Missense Mutation (SNP) | VAF 6/105 reads (6%) | SIFT tolerated (0.19); PolyPhen possibly damaging (0.835); catalogued as COSV54863526, COSV54867762; called by muse, mutect2
- CDH9 | c.297T>G p.S99R | Missense Mutation (SNP) | VAF 18/202 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.47); catalogued as COSV50274035; called by muse, mutect2
- CDK14 | c.1180G>T p.D394Y (on ENST00000380050 / NM_001287135.2; = p.D376Y on NM_012395.3) | Missense Mutation (SNP) | VAF 23/197 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.817); catalogued as COSV56033227; called by muse, mutect2, varscan2
- CDKL5 | c.452T>A p.L151Q | Missense Mutation (SNP) | VAF 11/336 reads (3%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.959); catalogued as COSV66111069; called by muse, mutect2
- CEACAM21 | c.2T>A p.M1? | Translation Start Site (SNP) | VAF 6/93 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51813881; called by muse, mutect2
- CEP120 | c.679G>T p.G227* | Nonsense Mutation (SNP) | VAF 20/139 reads (14%) | catalogued as COSV60265260; called by muse, mutect2, varscan2
- CHMP6 | c.496-2A>G p.X166_splice | Splice Site (SNP) | VAF 16/250 reads (6%) | catalogued as COSV57327326; called by muse, mutect2
- CHRM5 | c.955C>A p.P319T | Missense Mutation (SNP) | VAF 30/256 reads (12%) | SIFT tolerated (0.39); PolyPhen benign (0.061); catalogued as COSV67247257; called by muse, mutect2
- CNGB3 | c.256C>A p.P86T | Missense Mutation (SNP) | VAF 58/718 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.086); catalogued as COSV60685532, COSV60688836; called by muse, mutect2
- COL25A1 | c.670C>A p.P224T | Missense Mutation (SNP) | VAF 14/224 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.021); catalogued as COSV101211490, COSV67649583; called by muse, mutect2
- COL4A5 | c.4837G>T p.A1613S | Missense Mutation (SNP) | VAF 18/258 reads (7%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.791); catalogued as COSV60360618; called by muse, mutect2
- COL9A1 | c.1907C>G p.P636R | Missense Mutation (SNP) | VAF 13/174 reads (7%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.959); catalogued as rs1408429826, COSV57882805; called by muse, mutect2
- COL9A2 | c.837G>T p.K279N | Missense Mutation (SNP) | VAF 13/324 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.915); catalogued as COSV65607442; called by muse, mutect2
- CPA4 | c.935A>T p.Q312L | Missense Mutation (SNP) | VAF 38/371 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55983049; called by muse, mutect2, varscan2
- CPSF6 | c.559G>T p.G187C | Missense Mutation (SNP) | VAF 20/269 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV57014185; called by muse, mutect2
- CREB5 | c.61C>A p.P21T (on ENST00000357727 / NM_182898.4; = p.P14T on NM_004904.3) | Missense Mutation (SNP) | VAF 25/225 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV63220248; called by muse, mutect2, varscan2
- CRISP2 | c.323C>A p.S108Y | Missense Mutation (SNP) | VAF 12/180 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.587); catalogued as COSV59254437; called by muse, mutect2
- CRNKL1 | c.41C>T p.T14I | Missense Mutation (SNP) | VAF 18/198 reads (9%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.585); catalogued as COSV55627437; called by muse, mutect2
- CSMD1 | c.7306A>T p.T2436S (on ENST00000520002; = p.T2435S on NM_033225.6) | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT deleterious (0.03); PolyPhen benign (0.001); catalogued as rs1212743426, COSV59316030; called by muse, mutect2
- CSMD3 | c.6841G>T p.A2281S (on ENST00000297405 / NM_001363185.1; = p.A2177S on NM_052900.3) | Missense Mutation (SNP) | VAF 27/141 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.909); catalogued as COSV52165395; called by muse, mutect2, varscan2
- CSMD3 | c.5894G>C p.C1965S (on ENST00000297405 / NM_001363185.1; = p.C1861S on NM_052900.3) | Missense Mutation (SNP) | VAF 10/164 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52165413, COSV99830849; called by muse, mutect2
- CSMD3 | c.5284T>A p.C1762S (on ENST00000297405 / NM_001363185.1; = p.C1658S on NM_052900.3) | Missense Mutation (SNP) | VAF 23/110 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.145); catalogued as COSV52165428; called by muse, mutect2, varscan2
- CTNNA2 | c.1291-2A>T p.X431_splice | Splice Site (SNP) | VAF 8/80 reads (10%) | catalogued as COSV58149589; called by muse, mutect2
- CUX1 | c.1570G>T p.A524S (on ENST00000437600 / NM_181500.4; = p.A526S on NM_001913.5) | Missense Mutation (SNP) | VAF 5/34 reads (15%) | SIFT tolerated (0.45); PolyPhen benign (0.036); catalogued as COSV99475219; called by muse, mutect2
- DCAF4L2 | c.958G>T p.V320L | Missense Mutation (SNP) | VAF 13/96 reads (14%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100150678, COSV60478239; called by muse, mutect2, varscan2
- DCLRE1B | c.515A>C p.H172P | Missense Mutation (SNP) | VAF 20/167 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.908); catalogued as COSV56724608; called by muse, mutect2, varscan2
- DDX18 | c.333G>T p.K111N | Missense Mutation (SNP) | VAF 19/140 reads (14%) | SIFT deleterious (0.02); PolyPhen benign (0.136); catalogued as COSV54306391, COSV99604507; called by muse, mutect2, varscan2
- DDX55 | c.247-2A>T p.X83_splice | Splice Site (SNP) | VAF 5/49 reads (10%) | catalogued as COSV53015972; called by muse, mutect2, varscan2
- DIP2B | c.1115-2A>T p.X372_splice | Splice Site (SNP) | VAF 30/210 reads (14%) | catalogued as COSV56583158; called by muse, mutect2, varscan2
- DLG2 | c.1904G>T p.S635I | Missense Mutation (SNP) | VAF 12/156 reads (8%) | SIFT deleterious (0.03); PolyPhen benign (0.042); catalogued as COSV54639796, COSV54646018; called by muse, mutect2
- DLGAP2 | c.1625C>T p.S542F | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV70093565, COSV70097468; called by muse, mutect2, varscan2
- DMBX1 | c.886G>T p.A296S | Missense Mutation (SNP) | VAF 14/67 reads (21%) | SIFT tolerated, low confidence (0.79); PolyPhen benign (0.028); catalogued as COSV63601942; called by muse, mutect2, varscan2
- DNAH5 | c.8275G>T p.V2759L | Missense Mutation (SNP) | VAF 16/93 reads (17%) | SIFT deleterious (0.04); PolyPhen benign (0.077); catalogued as COSV54220811; called by muse, mutect2, varscan2
- DOP1B | c.2482G>T p.A828S | Missense Mutation (SNP) | VAF 8/129 reads (6%) | SIFT deleterious (0.05); PolyPhen benign (0.139); catalogued as COSV67693136; called by muse, mutect2
- DOP1B | c.2633G>T p.R878L | Missense Mutation (SNP) | VAF 14/168 reads (8%) | SIFT tolerated (0.83); PolyPhen benign (0.007); catalogued as rs140431407; called by muse, mutect2
- DYNC2LI1 | c.1055G>T p.*352Lext*21 | Nonstop Mutation (SNP) | VAF 7/53 reads (13%) | catalogued as COSV53183277; called by muse, mutect2
- DZIP3 | c.1910G>T p.G637V | Missense Mutation (SNP) | VAF 17/233 reads (7%) | SIFT tolerated, low confidence (0.25); PolyPhen benign (0); catalogued as COSV64311890; called by muse, mutect2
- EDRF1 | c.2905A>T p.T969S (on ENST00000356792 / NM_001202438.2; = p.T935S on NM_015608.2) | Missense Mutation (SNP) | VAF 19/156 reads (12%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.994); catalogued as COSV61763580; called by muse, mutect2, varscan2
- EFCAB5 | c.3350G>T p.G1117V | Missense Mutation (SNP) | VAF 19/124 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57929212, COSV57934338; called by muse, mutect2, varscan2
- EIF1AD | c.353+1G>T p.X118_splice | Splice Site (SNP) | VAF 64/756 reads (8%) | catalogued as COSV56463472; called by muse, mutect2
- EP400 | c.8061G>T p.Q2687H | Missense Mutation (SNP) | VAF 18/168 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.995); catalogued as COSV57770585; called by muse, mutect2, varscan2
- EPG5 | c.4609G>A p.V1537M | Missense Mutation (SNP) | VAF 11/128 reads (9%) | SIFT tolerated (0.27); PolyPhen benign (0.009); catalogued as COSV56348832; called by muse, mutect2
- EPPK1 | c.6236G>T p.G2079V | Missense Mutation (SNP) | VAF 15/107 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV73261119; called by muse, mutect2, varscan2
- ERBB4 | c.2405G>T p.G802V | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61483119; called by muse, mutect2
- ERICH3 | c.3391C>A p.P1131T | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious (0.01); PolyPhen benign (0.294); catalogued as COSV58605436, COSV58616108; called by muse, mutect2, varscan2
- EXOSC9 | c.384+1G>T p.X128_splice | Splice Site (SNP) | VAF 9/83 reads (11%) | catalogued as COSV54665833; called by muse, mutect2, varscan2
- EYA4 | c.485C>A p.A162D | Missense Mutation (SNP) | VAF 33/300 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.444); catalogued as rs745782248, COSV62050369; called by muse, mutect2
- F10 | c.1250G>T p.G417V | Missense Mutation (SNP) | VAF 11/186 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65021543; called by muse, mutect2
- FAM47C | c.1971G>C p.E657D | Missense Mutation (SNP) | VAF 10/248 reads (4%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.967); catalogued as COSV63724899, COSV63726194; called by muse, mutect2
- FGF9 | c.244A>G p.I82V | Missense Mutation (SNP) | VAF 7/151 reads (5%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV66644498; called by muse, mutect2
- FLG2 | c.6065C>T p.T2022I | Missense Mutation (SNP) | VAF 74/784 reads (9%) | SIFT tolerated (0.12); PolyPhen benign (0.011); catalogued as COSV66168324; called by muse, mutect2
- FREM2 | c.6385A>G p.K2129E | Missense Mutation (SNP) | VAF 11/113 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.139); catalogued as COSV54836056; called by muse, mutect2, varscan2
- FSHB | c.248G>A p.G83D | Missense Mutation (SNP) | VAF 6/106 reads (6%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.996); catalogued as COSV54221676; called by muse, mutect2
- FSTL5 | c.1228G>T p.A410S | Missense Mutation (SNP) | VAF 16/300 reads (5%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.801); catalogued as COSV100053991, COSV60186309; called by muse, mutect2
- FTCD | c.572G>T p.G191V | Missense Mutation (SNP) | VAF 10/154 reads (6%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.609); catalogued as COSV52425107, COSV52431419; called by muse, mutect2
- GABRA6 | c.509G>T p.C170F | Missense Mutation (SNP) | VAF 12/162 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1470584188, COSV50880298; called by muse, mutect2
- GALNT13 | c.1601C>G p.P534R | Missense Mutation (SNP) | VAF 13/121 reads (11%) | SIFT tolerated (0.07); PolyPhen probably damaging (0.998); catalogued as COSV67218810; called by muse, mutect2
- GFPT1 | c.1185T>G p.S395R (on ENST00000357308 / NM_001244710.2; = p.S377R on NM_002056.4) | Missense Mutation (SNP) | VAF 15/326 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV61947691; called by muse, mutect2
- GID4 | c.652G>A p.D218N | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.08); PolyPhen probably damaging (1); catalogued as COSV52008721; called by muse, mutect2, varscan2
- GLB1L3 | c.664G>T p.V222L | Missense Mutation (SNP) | VAF 5/86 reads (6%) | SIFT tolerated (0.08); PolyPhen benign (0.434); catalogued as COSV66281470; called by muse, mutect2
- GMFG | c.150G>T p.Q50H | Missense Mutation (SNP) | VAF 14/360 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.514); catalogued as COSV53419202; called by muse, mutect2
- GNL3L | c.1020G>C p.Q340H | Missense Mutation (SNP) | VAF 6/60 reads (10%) | SIFT tolerated (0.06); PolyPhen benign (0.151); catalogued as COSV60576129; called by muse, mutect2, varscan2
- GPCPD1 | c.1966G>C p.E656Q | Missense Mutation (SNP) | VAF 17/249 reads (7%) | SIFT tolerated (0.58); PolyPhen benign (0.026); catalogued as COSV66830665; called by muse, mutect2
- GPR139 | c.595T>A p.F199I | Missense Mutation (SNP) | VAF 11/104 reads (11%) | SIFT tolerated (0.11); PolyPhen probably damaging (1); catalogued as COSV58502687; called by muse, mutect2, varscan2
- GPR142 | c.671G>T p.R224L | Missense Mutation (SNP) | VAF 8/81 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100170869, COSV59519210; called by muse, mutect2, varscan2
- GPR149 | c.1912A>G p.S638G | Missense Mutation (SNP) | VAF 22/130 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV67667030; called by muse, mutect2, varscan2
- GREB1 | c.3935A>T p.Y1312F | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.99); catalogued as COSV52185877; called by muse, mutect2, varscan2
- HAL | c.1648G>T p.E550* | Nonsense Mutation (SNP) | VAF 6/136 reads (4%) | catalogued as COSV99701328; called by muse, mutect2
- HAVCR2 | c.825G>T p.E275D | Missense Mutation (SNP) | VAF 13/95 reads (14%) | SIFT deleterious (0.01); PolyPhen benign (0.385); catalogued as COSV57152799; called by muse, mutect2, varscan2
- HCN1 | c.2190G>T p.M730I | Missense Mutation (SNP) | VAF 11/57 reads (19%) | SIFT tolerated, low confidence (0.68); PolyPhen benign (0); catalogued as COSV57507272, COSV57513123; called by muse, mutect2, varscan2
- HDAC9 | c.1604T>A p.V535E | Missense Mutation (SNP) | VAF 9/83 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1562820981, COSV67772227; called by muse, mutect2
- HEXA | c.1330G>A p.G444S | Missense Mutation (SNP) | VAF 27/206 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.948); catalogued as COSV51506224; called by muse, mutect2, varscan2
- HFM1 | c.2447G>T p.C816F | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); catalogued as COSV54026241; called by muse, mutect2
- HGF | c.835C>A p.R279S | Missense Mutation (SNP) | VAF 12/141 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.005); catalogued as COSV55957167, COSV55957898; called by muse, mutect2
- HIVEP2 | c.45G>T p.R15S | Missense Mutation (SNP) | VAF 11/315 reads (3%) | SIFT deleterious (0.02); PolyPhen benign (0.03); catalogued as COSV50010170; called by muse, mutect2
- HLF | c.386G>T p.R129L | Missense Mutation (SNP) | VAF 26/276 reads (9%) | SIFT tolerated (0.39); PolyPhen benign (0.018); catalogued as COSV56829793; called by muse, mutect2
- HMCN1 | c.8650G>T p.V2884L | Missense Mutation (SNP) | VAF 36/358 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as COSV54896229; called by muse, mutect2
- HNF4A | c.677A>T p.E226V | Missense Mutation (SNP) | VAF 26/371 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV57382370; called by muse, mutect2
- HSPA6 | c.297G>T p.E99D | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT tolerated, low confidence (1); PolyPhen benign (0); catalogued as COSV59060840; called by muse, mutect2
- HSPE1 | c.229G>T p.G77* | Nonsense Mutation (SNP) | VAF 10/207 reads (5%) | catalogued as COSV99291426; called by muse, mutect2
- IGKV1-5 | c.136C>G p.R46G | Missense Mutation (SNP) | VAF 22/248 reads (9%) | SIFT deleterious (0.01); PolyPhen benign (0.027); catalogued as rs781688607; called by muse, mutect2
- IGKV4-1 | c.94G>T p.A32S | Missense Mutation (SNP) | VAF 17/115 reads (15%) | SIFT tolerated (1); PolyPhen benign (0.091); catalogued as rs148071875; called by muse, mutect2, varscan2
- IL1RN | c.327C>A p.N109K (on ENST00000409930 / NM_173842.3; = p.N91K on NM_000577.5) | Missense Mutation (SNP) | VAF 7/107 reads (7%) | SIFT deleterious (0.05); PolyPhen benign (0.255); catalogued as COSV99381526; called by muse, mutect2
- IL3 | c.368G>T p.W123L | Missense Mutation (SNP) | VAF 21/167 reads (13%) | SIFT tolerated (0.69); PolyPhen benign (0.036); catalogued as COSV57308860; called by muse, mutect2, varscan2
- INHBA | c.455G>T p.R152L | Missense Mutation (SNP) | VAF 15/132 reads (11%) | SIFT deleterious (0); PolyPhen benign (0.209); catalogued as rs377167564, COSV54221218; called by muse, mutect2, varscan2
- IQGAP1 | c.3179G>T p.R1060L | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51584840; called by muse, mutect2
- IRX2 | c.505C>T p.R169C | Missense Mutation (SNP) | VAF 14/218 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57410946; called by muse, mutect2
- ITGA10 | c.2024G>T p.C675F | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT deleterious (0.03); PolyPhen probably damaging (1); catalogued as COSV65197168; called by muse, mutect2
- ITIH6 | c.3482G>T p.R1161L | Missense Mutation (SNP) | VAF 14/104 reads (13%) | SIFT tolerated (0.74); PolyPhen benign (0.005); catalogued as COSV54488614, COSV99513570; called by muse, mutect2, varscan2
- JAK2 | c.2605G>A p.D869N | Missense Mutation (SNP) | VAF 22/227 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.977); catalogued as COSV67606433; called by muse, mutect2
- KALRN | c.6201G>T p.Q2067H (on ENST00000360013 / NM_001024660.4; = p.Q370H on NM_007064.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 15/128 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); catalogued as COSV52255147; called by muse, mutect2, varscan2
- KANSL1 | c.1808G>T p.R603M | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV52267723; called by muse, mutect2
- KCNJ2 | c.187G>T p.E63* | Nonsense Mutation (SNP) | VAF 11/119 reads (9%) | catalogued as COSV54661451; called by muse, mutect2
- KCNJ2 | c.540G>T p.M180I | Missense Mutation (SNP) | VAF 18/138 reads (13%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.56); catalogued as COSV54661465; called by muse, mutect2, varscan2
- KCNJ5 | c.997T>A p.F333I | Missense Mutation (SNP) | VAF 15/242 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.971); catalogued as COSV57965579; called by muse, mutect2
- KHSRP | c.862G>C p.D288H | Missense Mutation (SNP) | VAF 7/64 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as COSV67919638; called by muse, mutect2
- KIF2B | c.1486G>A p.A496T | Missense Mutation (SNP) | VAF 9/63 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.688); catalogued as COSV52129805; called by muse, mutect2, varscan2
- KIF2B | c.2002G>T p.V668L | Missense Mutation (SNP) | VAF 7/67 reads (10%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.001); catalogued as COSV52129814; called by muse, mutect2
- KLHL4 | c.1247T>C p.M416T | Missense Mutation (SNP) | VAF 6/83 reads (7%) | SIFT deleterious (0.03); PolyPhen benign (0.003); catalogued as COSV64141768; called by muse, mutect2
- KLRC1 | c.665G>T p.G222V | Missense Mutation (SNP) | VAF 16/266 reads (6%) | SIFT tolerated (0.29); PolyPhen probably damaging (0.991); catalogued as COSV61725149; called by muse, mutect2
- KRCC1 | c.665G>C p.S222T | Missense Mutation (SNP) | VAF 11/193 reads (6%) | SIFT tolerated (0.06); PolyPhen benign (0.011); catalogued as COSV61251419; called by muse, mutect2
- KRT26 | c.421A>G p.I141V | Missense Mutation (SNP) | VAF 7/126 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.424); catalogued as COSV59413937; called by muse, mutect2
- KRT9 | c.157T>A p.Y53N | Missense Mutation (SNP) | VAF 8/76 reads (11%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.143); catalogued as COSV55852800; called by muse, mutect2, varscan2
- L1CAM | c.994G>T p.A332S | Missense Mutation (SNP) | VAF 4/35 reads (11%) | SIFT tolerated (0.07); PolyPhen benign (0.151); catalogued as COSV100648990; called by muse, mutect2
- LHX8 | c.1034C>G p.P345R | Missense Mutation (SNP) | VAF 23/337 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.621); catalogued as COSV53956169; called by muse, mutect2
- LRIT1 | c.1043C>T p.P348L | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.05); PolyPhen benign (0.015); catalogued as rs1184782876, COSV64512522; called by mutect2, varscan2
- LRP1B | c.4741C>T p.R1581C | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT deleterious (0.01); PolyPhen benign (0.306); catalogued as rs1035316456, COSV67211958; called by muse, mutect2
- LRRC7 | c.1320+1G>T p.X440_splice (on ENST00000651989 / NM_001370785.2; = p.X407_splice on NM_001330635.3 and 2 other RefSeq transcripts) | Splice Site (SNP) | VAF 11/60 reads (18%) | catalogued as COSV50448114; called by muse, mutect2, varscan2
- LRRTM4 | c.955A>T p.I319F | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as COSV69139884; called by muse, mutect2
- LTBP1 | c.3482-1G>T p.X1161_splice (on ENST00000404816 / NM_206943.4; = p.X835_splice on NM_000627.4) | Splice Site (SNP) | VAF 16/99 reads (16%) | catalogued as COSV55378677, COSV99698705; called by muse, mutect2, varscan2
- MAPK9 | c.872-2A>T p.X291_splice | Splice Site (SNP) | VAF 13/374 reads (3%) | catalogued as COSV58121564; called by muse, mutect2
- MAPT | c.892G>T p.D298Y (on ENST00000262410 / NM_001377265.1; = p.D223Y on NM_016835.4) | Missense Mutation (SNP) | VAF 5/38 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.964); catalogued as COSV52239895; called by muse, mutect2, varscan2
- MAST4 | c.6305G>C p.S2102T (on ENST00000403625 / NM_001164664.2; = p.S1913T on NM_015183.3) | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.007); catalogued as COSV55119365; called by muse, mutect2, varscan2
- MBTPS2 | c.106G>A p.D36N | Missense Mutation (SNP) | VAF 8/216 reads (4%) | SIFT tolerated (0.38); PolyPhen benign (0.003); catalogued as COSV63410882, COSV63411282; called by muse, mutect2
- MDM1 | c.1415G>T p.R472M | Missense Mutation (SNP) | VAF 38/550 reads (7%) | SIFT tolerated (0.05); PolyPhen benign (0.022); catalogued as COSV57445694; called by muse, mutect2
- MMP16 | c.1155G>T p.W385C | Missense Mutation (SNP) | VAF 10/140 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54162263; called by muse, mutect2
- MMP16 | c.757G>T p.G253* | Nonsense Mutation (SNP) | VAF 10/84 reads (12%) | catalogued as COSV54162268, COSV99685461; called by muse, mutect2
- MOGAT3 | c.692C>A p.S231Y | Missense Mutation (SNP) | VAF 7/48 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56174479, COSV99777098; called by muse, mutect2, varscan2
- MS4A7 | c.409G>T p.D137Y | Missense Mutation (SNP) | VAF 7/76 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV55729659; called by muse, mutect2
- MUC16 | c.23075C>T p.S7692F | Missense Mutation (SNP) | VAF 8/122 reads (7%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.649); catalogued as COSV67462391; called by muse, mutect2
- MYH1 | c.505G>T p.D169Y | Missense Mutation (SNP) | VAF 33/292 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56847298; called by muse, mutect2, varscan2
- MYH6 | c.164A>T p.E55V | Missense Mutation (SNP) | VAF 77/860 reads (9%) | SIFT deleterious (0.02); PolyPhen benign (0.267); catalogued as rs1317811281, COSV62449877; called by muse, mutect2
- NCAM2 | c.1881T>G p.I627M | Missense Mutation (SNP) | VAF 6/91 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.954); catalogued as rs1349488966, COSV53071582; called by muse, mutect2
- NCOA6 | c.5578A>G p.T1860A | Missense Mutation (SNP) | VAF 15/160 reads (9%) | SIFT tolerated, low confidence (0.21); PolyPhen benign (0); catalogued as COSV62863216; called by muse, mutect2
- NCR1 | c.3G>A p.M1? | Translation Start Site (SNP) | VAF 16/230 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as COSV52556472; called by muse, mutect2
- NCR2 | c.464G>A p.C155Y | Missense Mutation (SNP) | VAF 18/124 reads (15%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.447); catalogued as COSV66100527; called by muse, mutect2, varscan2
- NEBL | c.1360G>T p.E454* | Nonsense Mutation (SNP) | VAF 35/266 reads (13%) | catalogued as COSV65802680; called by muse, mutect2, varscan2
- NLRP3 | c.352T>A p.L118I | Missense Mutation (SNP) | VAF 20/208 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV60223449; called by muse, mutect2
- NNMT | c.440A>G p.Q147R | Missense Mutation (SNP) | VAF 11/229 reads (5%) | SIFT tolerated (0.33); PolyPhen benign (0); catalogued as COSV55473637; called by muse, mutect2
- NOL11 | c.1284C>G p.D428E | Missense Mutation (SNP) | VAF 28/202 reads (14%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.787); catalogued as COSV53523193; called by muse, mutect2, varscan2
- NOS1AP | c.893A>T p.Q298L | Missense Mutation (SNP) | VAF 9/86 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.165); catalogued as COSV62634316; called by muse, mutect2
- NPAP1 | c.3352G>T p.A1118S | Missense Mutation (SNP) | VAF 9/223 reads (4%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.013); catalogued as rs945414292, COSV61506418; called by muse, mutect2
- OBSCN | c.6839G>T p.R2280L | Missense Mutation (SNP) | VAF 23/208 reads (11%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.759); catalogued as CM142523, COSV52769481, COSV99484604; called by muse, mutect2, varscan2
- OLFML1 | c.407T>A p.L136Q | Missense Mutation (SNP) | VAF 5/27 reads (19%) | SIFT tolerated (0.37); PolyPhen benign (0.024); catalogued as COSV61402558; called by muse, mutect2
- OPHN1 | c.408G>C p.K136N | Missense Mutation (SNP) | VAF 8/150 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV62781969; called by muse, mutect2
- OPN1SW | c.832C>A p.H278N | Missense Mutation (SNP) | VAF 5/47 reads (11%) | SIFT tolerated (0.5); PolyPhen probably damaging (0.998); catalogued as COSV50821606; called by muse, mutect2, varscan2
- OR10P1 | c.796G>A p.G266S | Missense Mutation (SNP) | VAF 16/194 reads (8%) | SIFT tolerated (1); PolyPhen benign (0.056); catalogued as rs1475543338, COSV59007143; called by muse, mutect2
- OR10Q1 | c.339C>A p.S113R | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.04); PolyPhen benign (0.372); catalogued as COSV100372214; called by muse, mutect2
- OR10S1 | c.854C>T p.A285V | Missense Mutation (SNP) | VAF 20/214 reads (9%) | SIFT tolerated (1); PolyPhen benign (0.007); catalogued as rs1262477675, COSV73342765, COSV73342823, COSV73342919; called by muse, mutect2
- OR11L1 | c.733C>A p.L245M | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100869406, COSV63315781; called by muse, mutect2
- OR11L1 | c.732C>A p.H244Q | Missense Mutation (SNP) | VAF 9/144 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1035849674, COSV63313712, COSV63314026; called by muse, mutect2
- OR1L4 | c.450C>A p.C150* | Nonsense Mutation (SNP) | VAF 21/358 reads (6%) | catalogued as COSV52340257; called by muse, mutect2
- OR2F1 | c.47G>T p.G16V | Missense Mutation (SNP) | VAF 25/367 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV67331293; called by muse, mutect2
- OR2G2 | c.529G>T p.V177L | Missense Mutation (SNP) | VAF 19/310 reads (6%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV60740339; called by muse, mutect2
- OR2M7 | c.325G>T p.G109C | Missense Mutation (SNP) | VAF 16/362 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV58738257, COSV58738829; called by muse, mutect2
- OR2W3 | c.631T>A p.L211M | Missense Mutation (SNP) | VAF 30/285 reads (11%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as COSV64456715; called by muse, mutect2, varscan2
- OR4A15 | c.417T>G p.C139W | Missense Mutation (SNP) | VAF 17/395 reads (4%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.992); catalogued as COSV59034975; called by muse, mutect2
- OR4C6 | c.650C>A p.T217K | Missense Mutation (SNP) | VAF 13/158 reads (8%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.429); catalogued as rs150924885, COSV58603583, COSV58605431; called by muse, mutect2
- OR4S2 | c.680C>A p.S227* | Nonsense Mutation (SNP) | VAF 10/190 reads (5%) | catalogued as COSV100412604; called by muse, mutect2
- OR7D2 | c.64G>T p.E22* | Nonsense Mutation (SNP) | VAF 7/64 reads (11%) | catalogued as COSV100712972, COSV60140477; called by muse, mutect2, varscan2
- OR8D4 | c.544G>T p.V182F | Missense Mutation (SNP) | VAF 18/398 reads (5%) | SIFT tolerated (0.23); PolyPhen benign (0.014); catalogued as COSV58430230; called by muse, mutect2
- OXR1 | c.2056G>A p.D686N (on ENST00000442977 / NM_001198532.1; = p.D658N on NM_018002.3) | Missense Mutation (SNP) | VAF 31/133 reads (23%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.521); catalogued as COSV52425135; called by muse, mutect2, varscan2
- PCDHGA2 | c.1233C>A p.D411E | Missense Mutation (SNP) | VAF 9/71 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as rs756707441, COSV99534869; called by muse, mutect2, varscan2
- PCSK5 | c.1334G>T p.G445V | Missense Mutation (SNP) | VAF 18/174 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV65088178; called by muse, mutect2, varscan2
- PCSK5 | c.3450G>T p.Q1150H | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT tolerated (0.13); PolyPhen benign (0.176); catalogued as COSV101377325; called by muse, mutect2, varscan2
- PDE3A | c.2242G>T p.D748Y | Missense Mutation (SNP) | VAF 7/89 reads (8%) | SIFT deleterious (0.01); PolyPhen benign (0.398); catalogued as COSV100762012, COSV62982062; called by muse, mutect2
- PDGFRA | c.2494G>A p.V832M | Missense Mutation (SNP) | VAF 19/260 reads (7%) | SIFT tolerated (0.05); PolyPhen probably damaging (1); catalogued as rs1315803700, COSV57267544; ClinVar: uncertain significance; called by muse, mutect2
- PHEX | c.508C>G p.L170V | Missense Mutation (SNP) | VAF 47/524 reads (9%) | SIFT tolerated (0.4); PolyPhen benign (0.063); catalogued as rs755595286, COSV65075223; called by muse, mutect2
- PI15 | c.17C>A p.A6D | Missense Mutation (SNP) | VAF 91/694 reads (13%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.037); catalogued as rs1193304783, COSV52641017; called by muse, mutect2, varscan2
- PI4KA | c.184G>T p.V62L | Missense Mutation (SNP) | VAF 8/154 reads (5%) | SIFT tolerated (0.69); PolyPhen benign (0.003); catalogued as COSV55409923; called by muse, mutect2
- PKHD1 | c.252G>T p.L84F | Missense Mutation (SNP) | VAF 16/392 reads (4%) | SIFT tolerated (0.35); PolyPhen benign (0.007); catalogued as COSV61873013; called by muse, mutect2
- PLCXD3 | c.340C>A p.H114N | Missense Mutation (SNP) | VAF 20/192 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as COSV60608218, COSV60615139; called by muse, mutect2
- PLEKHA6 | c.1775T>C p.L592P | Missense Mutation (SNP) | VAF 10/82 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV55332852; called by muse, mutect2
- PLG | c.480G>T p.Q160H | Missense Mutation (SNP) | VAF 18/343 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.006); catalogued as COSV51982526; called by muse, mutect2
- PLK1 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 37/809 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1041097622, COSV55621786; called by muse, mutect2
- PML | c.1115G>T p.R372L | Missense Mutation (SNP) | VAF 4/58 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.019); catalogued as rs1309900464, COSV51445748; called by muse, mutect2
- POLR3B | c.818A>T p.Q273L | Missense Mutation (SNP) | VAF 18/252 reads (7%) | SIFT tolerated (0.64); PolyPhen benign (0); catalogued as COSV57278437; called by muse, mutect2
- PPHLN1 | c.1318A>T p.M440L | Missense Mutation (SNP) | VAF 11/99 reads (11%) | SIFT deleterious, low confidence (0.04); PolyPhen benign (0.007); catalogued as COSV56730512, COSV56735190; called by muse, mutect2, varscan2
- PPP1R13L | c.755A>T p.E252V | Missense Mutation (SNP) | VAF 25/137 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.878); catalogued as COSV62908394; called by muse, mutect2, varscan2
- PPRC1 | c.3607G>T p.G1203C | Missense Mutation (SNP) | VAF 8/90 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.826); catalogued as COSV99531500; called by muse, mutect2
- PRDM13 | c.463C>A p.H155N | Missense Mutation (SNP) | VAF 9/78 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV65029574, COSV65030502; called by muse, mutect2, varscan2
- PREB | c.1141C>T p.H381Y | Missense Mutation (SNP) | VAF 22/209 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV53205821; called by muse, mutect2, varscan2
- PTDSS1 | c.1099G>T p.V367F | Missense Mutation (SNP) | VAF 37/302 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.936); catalogued as COSV61264531; called by muse, mutect2, varscan2
- PTPRK | c.3841-1G>C p.X1281_splice (on ENST00000368215 / NM_001291984.2; = p.X1282_splice on NM_002844.4) | Splice Site (SNP) | VAF 8/88 reads (9%) | catalogued as COSV63896315; called by muse, mutect2
- PXDNL | c.2519C>A p.P840H | Missense Mutation (SNP) | VAF 6/58 reads (10%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.981); catalogued as COSV62486387; called by muse, mutect2
- RABGAP1L | c.875+1G>T p.X292_splice | Splice Site (SNP) | VAF 8/126 reads (6%) | catalogued as COSV52291737; called by muse, mutect2
- RAD23B | c.733G>T p.A245S | Missense Mutation (SNP) | VAF 4/63 reads (6%) | SIFT tolerated (0.45); PolyPhen benign (0.024); catalogued as COSV100787667; called by muse, mutect2
- RESF1 | c.2310G>T p.E770D | Missense Mutation (SNP) | VAF 26/82 reads (32%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as COSV57021740; called by muse, mutect2, varscan2
- RGS16 | c.157A>T p.R53* | Nonsense Mutation (SNP) | VAF 3/37 reads (8%) | catalogued as COSV100842489, COSV62375667; called by muse, mutect2
- RIMS2 | c.2815C>T p.P939S (on ENST00000666250 / NM_001348490.2; = p.P747S on NM_014677.5 and 7 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.979); catalogued as rs746467834, COSV51676458, COSV99202274; called by muse, mutect2, varscan2
- RNF17 | c.1819G>T p.V607F | Missense Mutation (SNP) | VAF 9/134 reads (7%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.971); catalogued as COSV99692748; called by muse, mutect2
- RP1 | c.4955G>T p.R1652L | Missense Mutation (SNP) | VAF 27/177 reads (15%) | SIFT deleterious (0.03); PolyPhen benign (0.081); catalogued as rs760740229, CM104294, COSV55115631, COSV55120271; called by muse, mutect2, varscan2
- RP1L1 | c.5399G>T p.R1800M | Missense Mutation (SNP) | VAF 34/454 reads (7%) | SIFT tolerated (0.08); PolyPhen benign (0.013); catalogued as COSV66754447; called by muse, mutect2
- RPN2 | c.215G>A p.C72Y | Missense Mutation (SNP) | VAF 15/199 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV52905270; called by muse, mutect2
- RUNX1T1 | c.88G>T p.D30Y | Missense Mutation (SNP) | VAF 13/177 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0); catalogued as COSV56144761; called by muse, mutect2
- RYR2 | c.1658G>T p.G553V | Missense Mutation (SNP) | VAF 5/87 reads (6%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.958); catalogued as COSV63675528, COSV63684932; called by muse, mutect2
- RYR2 | c.3824G>T p.G1275V | Missense Mutation (SNP) | VAF 15/296 reads (5%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as COSV100767519, COSV100769211; called by muse, mutect2
- SAMD9 | c.1226A>G p.Y409C | Missense Mutation (SNP) | VAF 8/54 reads (15%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.819); catalogued as COSV66074804; called by muse, mutect2, varscan2
- SCARF2 | c.1349T>A p.L450H | Missense Mutation (SNP) | VAF 9/92 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as COSV56732022; called by muse, mutect2
- SCFD1 | c.533G>T p.R178M | Missense Mutation (SNP) | VAF 20/212 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.855); catalogued as COSV61723717; called by muse, mutect2
- SELE | c.844C>A p.Q282K | Missense Mutation (SNP) | VAF 16/133 reads (12%) | SIFT tolerated (0.98); PolyPhen benign (0.007); catalogued as COSV60975101, COSV60977402; called by muse, mutect2, varscan2
- SERPINE1 | c.439G>T p.V147L | Missense Mutation (SNP) | VAF 63/771 reads (8%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.885); catalogued as COSV56169455; called by muse, mutect2
- SETX | c.6234G>T p.Q2078H | Missense Mutation (SNP) | VAF 7/65 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV56383773; called by muse, mutect2, varscan2
- SEZ6 | c.1261C>G p.R421G | Missense Mutation (SNP) | VAF 29/304 reads (10%) | SIFT deleterious (0.02); PolyPhen benign (0.122); catalogued as COSV57979349, COSV57979940; called by muse, mutect2, varscan2
- SHANK2 | c.4735C>T p.P1579S | Missense Mutation (SNP) | VAF 10/238 reads (4%) | SIFT tolerated (0.26); PolyPhen benign (0.209); catalogued as COSV53595869; called by muse, mutect2
- SI | c.2893-1G>T p.X965_splice | Splice Site (SNP) | VAF 12/82 reads (15%) | catalogued as COSV52276113; called by muse, mutect2
- SLC17A6 | c.662G>T p.G221V | Missense Mutation (SNP) | VAF 6/124 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54135859; called by muse, mutect2
- SLC1A6 | c.1349A>C p.Q450P | Missense Mutation (SNP) | VAF 11/119 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.944); catalogued as COSV55669930; called by muse, mutect2, varscan2
- SLC22A9 | c.288G>T p.W96C | Missense Mutation (SNP) | VAF 7/97 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV54166969; called by muse, mutect2
- SLC22A9 | c.581C>A p.P194H | Missense Mutation (SNP) | VAF 16/159 reads (10%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV54166985; called by muse, mutect2, varscan2
- SLC36A3 | c.399G>T p.W133C | Missense Mutation (SNP) | VAF 7/69 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV100077486; called by muse, mutect2
- SMG6 | c.972G>T p.K324N | Missense Mutation (SNP) | VAF 28/272 reads (10%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.224); catalogued as COSV53966435; called by muse, mutect2, varscan2
- SMIM21 | c.169G>T p.V57F | Missense Mutation (SNP) | VAF 23/166 reads (14%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.919); catalogued as COSV66894842; called by muse, mutect2, varscan2
- SOHLH2 | c.760G>T p.E254* | Nonsense Mutation (SNP) | VAF 8/122 reads (7%) | catalogued as COSV65901841; called by muse, mutect2
- SPDL1 | c.387G>T p.Q129H | Missense Mutation (SNP) | VAF 8/97 reads (8%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.999); catalogued as COSV54667877; called by muse, mutect2
- SPPL2C | c.386G>C p.C129S | Missense Mutation (SNP) | VAF 7/82 reads (9%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.863); catalogued as COSV61292335; called by muse, mutect2
- ST8SIA6 | c.419T>C p.V140A | Missense Mutation (SNP) | VAF 18/84 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0.298); catalogued as rs1363009980, COSV66467930; called by muse, mutect2, varscan2
- STK31 | c.1335G>T p.Q445H | Missense Mutation (SNP) | VAF 16/178 reads (9%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.751); catalogued as COSV63455684; called by muse, mutect2
- SVEP1 | c.8863C>T p.L2955F | Missense Mutation (SNP) | VAF 17/341 reads (5%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.583); catalogued as COSV52838639; called by muse, mutect2
- SYPL1 | c.133A>G p.I45V | Missense Mutation (SNP) | VAF 10/69 reads (14%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.754); catalogued as rs781088755, COSV50578855; called by muse, mutect2, varscan2
- TACC2 | c.5725G>C p.G1909R | Missense Mutation (SNP) | VAF 18/292 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.216); catalogued as COSV57754034; called by muse, mutect2
- TBX5 | c.1039C>G p.P347A | Missense Mutation (SNP) | VAF 20/246 reads (8%) | SIFT tolerated (0.12); PolyPhen benign (0.137); catalogued as COSV59860656; called by muse, mutect2
- TCTN2 | c.892-2A>T p.X298_splice | Splice Site (SNP) | VAF 8/106 reads (8%) | catalogued as COSV57632700; called by muse, mutect2
- TEX47 | c.38G>T p.R13M | Missense Mutation (SNP) | VAF 18/119 reads (15%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.724); catalogued as COSV51878829; called by muse, mutect2, varscan2
- TGIF2LX | c.145C>A p.H49N | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (0.59); PolyPhen benign (0.045); catalogued as COSV99383256; called by muse, mutect2, varscan2
- TIGAR | c.553G>T p.G185C | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.927); catalogued as COSV51627667; called by muse, mutect2
- TKTL2 | c.1459C>A p.P487T | Missense Mutation (SNP) | VAF 7/163 reads (4%) | SIFT tolerated (0.08); PolyPhen benign (0.015); catalogued as COSV54918549; called by muse, mutect2
- TLR7 | c.1249T>G p.F417V | Missense Mutation (SNP) | VAF 16/162 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.899); catalogued as COSV66124186; called by muse, mutect2
- TLR8 | c.659T>A p.L220Q (on ENST00000218032 / NM_138636.5; = p.L238Q on NM_016610.4) | Missense Mutation (SNP) | VAF 28/201 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54317604; called by muse, mutect2, varscan2
- TMEM187 | c.145C>T p.P49S | Missense Mutation (SNP) | VAF 8/218 reads (4%) | SIFT tolerated (0.1); PolyPhen probably damaging (0.999); catalogued as COSV64141565; called by muse, mutect2
- TMTC2 | c.84-1G>T p.X28_splice | Splice Site (SNP) | VAF 11/135 reads (8%) | catalogued as COSV58267273; called by muse, mutect2
- TNR | c.526A>T p.S176C | Missense Mutation (SNP) | VAF 25/236 reads (11%) | SIFT deleterious (0); PolyPhen possibly damaging (0.885); catalogued as COSV54882896; called by muse, mutect2, varscan2
- TOX4 | c.1453C>T p.Q485* | Nonsense Mutation (SNP) | VAF 12/178 reads (7%) | catalogued as COSV52968606; called by muse, mutect2
- TPM3 | c.708A>G p.A236= | Splice Region (SNP) | VAF 30/154 reads (19%) | catalogued as rs373670110; called by muse, mutect2, varscan2
- TPP2 | c.1016+1G>A p.X339_splice | Splice Site (SNP) | VAF 8/92 reads (9%) | catalogued as COSV65752345; called by muse, mutect2
- TRPV3 | c.1912G>T p.G638C | Missense Mutation (SNP) | VAF 6/43 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV56790936; called by muse, mutect2, varscan2
- TRPV5 | c.413C>A p.T138N | Missense Mutation (SNP) | VAF 26/212 reads (12%) | SIFT tolerated (0.18); PolyPhen benign (0.062); catalogued as COSV54685276; called by muse, mutect2, varscan2
- TSGA10 | c.835A>T p.K279* | Nonsense Mutation (SNP) | VAF 7/87 reads (8%) | catalogued as COSV61824516; called by muse, mutect2
- TTC5 | c.668A>T p.N223I | Missense Mutation (SNP) | VAF 24/342 reads (7%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.901); catalogued as COSV51870747, COSV99352073; called by muse, mutect2
- TTN | c.17008G>T p.G5670W (on ENST00000591111; = p.G4743W on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 22/242 reads (9%) | PolyPhen probably damaging (1); catalogued as COSV60017621; called by muse, mutect2
- UBE2Q2 | c.590G>T p.G197V | Missense Mutation (SNP) | VAF 40/420 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.686); catalogued as COSV51192818; called by muse, mutect2
- UHMK1 | c.399G>T p.W133C | Missense Mutation (SNP) | VAF 9/155 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56419899; called by muse, mutect2
- USH2A | c.6415G>T p.A2139S | Missense Mutation (SNP) | VAF 11/101 reads (11%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.836); catalogued as COSV56362028; called by muse, mutect2, varscan2
- USP11 | c.2189G>C p.R730P (on ENST00000218348; = p.R687P on NM_001371072.1) | Missense Mutation (SNP) | VAF 12/142 reads (8%) | SIFT tolerated (0.24); PolyPhen benign (0.04); catalogued as COSV54473479; called by muse, mutect2
- USP24 | c.2697G>T p.M899I | Missense Mutation (SNP) | VAF 8/58 reads (14%) | SIFT tolerated (0.23); PolyPhen possibly damaging (0.48); catalogued as COSV53766608; called by muse, mutect2
- USP29 | c.2207A>T p.Q736L | Missense Mutation (SNP) | VAF 9/96 reads (9%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.703); catalogued as COSV54142213; called by muse, mutect2
- USP31 | c.3415A>T p.R1139W | Missense Mutation (SNP) | VAF 11/86 reads (13%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.907); catalogued as COSV54851699; called by muse, mutect2, varscan2
- VAV2 | c.1533-2A>C p.X511_splice (on ENST00000371850 / NM_001134398.2; = p.X501_splice on NM_003371.4) | Splice Site (SNP) | VAF 12/156 reads (8%) | catalogued as COSV64081541; called by muse, mutect2
- VPS13D | c.5539C>A p.P1847T | Missense Mutation (SNP) | VAF 15/168 reads (9%) | SIFT tolerated (0.41); PolyPhen benign (0.009); catalogued as COSV50635242; called by muse, mutect2
- VWC2L | c.616T>A p.W206R | Missense Mutation (SNP) | VAF 24/419 reads (6%) | SIFT tolerated (1); PolyPhen benign (0.365); catalogued as COSV56969595; called by muse, mutect2
- WDR53 | c.995G>T p.G332V | Missense Mutation (SNP) | VAF 14/241 reads (6%) | SIFT tolerated (0.5); PolyPhen benign (0.034); catalogued as COSV60284037; called by muse, mutect2
- WDR64 | c.1063A>G p.S355G | Missense Mutation (SNP) | VAF 16/129 reads (12%) | SIFT tolerated (0.26); PolyPhen possibly damaging (0.581); catalogued as COSV63795354; called by muse, mutect2, varscan2
- WWP1 | c.283G>C p.G95R | Missense Mutation (SNP) | VAF 10/79 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55360691; called by muse, mutect2, varscan2
- WWP1 | c.284G>T p.G95V | Missense Mutation (SNP) | VAF 10/76 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99616036; called by muse, mutect2, varscan2
- YEATS2 | c.1151-1G>T p.X384_splice | Splice Site (SNP) | VAF 39/352 reads (11%) | catalogued as COSV59364837; called by muse, mutect2, varscan2
- ZBTB41 | c.1784G>T p.R595L | Missense Mutation (SNP) | VAF 13/151 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV66358679, COSV66359080; called by muse, mutect2
- ZBTB44 | c.652A>G p.R218G | Missense Mutation (SNP) | VAF 7/81 reads (9%) | SIFT tolerated (0.35); PolyPhen benign (0.149); catalogued as COSV63537112; called by muse, mutect2
- ZFHX3 | c.1635G>T p.R545S | Missense Mutation (SNP) | VAF 8/98 reads (8%) | SIFT tolerated, low confidence (0.07); PolyPhen benign (0.063); catalogued as rs1228571370, COSV51716715; called by muse, mutect2
- ZKSCAN2 | c.2551A>G p.R851G | Missense Mutation (SNP) | VAF 11/131 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.993); catalogued as COSV60156665; called by muse, mutect2
- ZNF479 | c.163C>A p.L55M | Missense Mutation (SNP) | VAF 9/195 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV58638045; called by muse, mutect2
- ZNF536 | c.155C>A p.P52H | Missense Mutation (SNP) | VAF 11/233 reads (5%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.117); catalogued as COSV62823218; called by muse, mutect2
- ZNF536 | c.1614G>C p.L538F | Missense Mutation (SNP) | VAF 11/146 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.694); catalogued as COSV62823222; called by muse, mutect2
- ZNF536 | c.2895G>T p.Q965H | Missense Mutation (SNP) | VAF 26/340 reads (8%) | SIFT tolerated, low confidence (0.08); PolyPhen benign (0.112); catalogued as COSV62823227; called by muse, mutect2
- ZNF543 | c.691G>T p.E231* | Nonsense Mutation (SNP) | VAF 9/136 reads (7%) | catalogued as COSV58627332, COSV58627459; called by muse, mutect2
- ZNF582 | c.211G>T p.V71L | Missense Mutation (SNP) | VAF 11/122 reads (9%) | SIFT tolerated (0.56); PolyPhen benign (0); catalogued as COSV56731987; called by muse, mutect2
- ZNF622 | c.1321C>T p.R441* | Nonsense Mutation (SNP) | VAF 20/194 reads (10%) | catalogued as COSV58073961; called by muse, mutect2
- ZSCAN20 | c.886C>T p.P296S | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT tolerated (0.11); PolyPhen benign (0.015); catalogued as COSV63682472; called by muse, mutect2
- ZSCAN5B | c.163G>T p.E55* | Nonsense Mutation (SNP) | VAF 8/58 reads (14%) | catalogued as COSV62839249; called by muse, mutect2, varscan2
- ZSWIM3 | c.2034G>T p.W678C | Missense Mutation (SNP) | VAF 27/198 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.819); catalogued as COSV54847111; called by muse, mutect2, varscan2
- IL7R | c.203dup p.N68Kfs*5 | Frame Shift Ins (INS) | VAF 49/321 reads (15%) | called by mutect2, pindel, varscan2
- KIR2DS4 | c.238del p.V80Ffs*11 | Frame Shift Del (DEL) | VAF 32/320 reads (10%) | called by mutect2, pindel, varscan2
- LAMA1 | c.5964del p.R1988Sfs*8 | Frame Shift Del (DEL) | VAF 6/64 reads (9%) | called by mutect2, varscan2
- MRC1 | c.2698G>T p.V900L | Missense Mutation (SNP) | VAF 22/510 reads (4%) | SIFT deleterious (0); PolyPhen possibly damaging (0.752); called by muse, mutect2
- SPHKAP | c.1513del p.T505Lfs*2 | Frame Shift Del (DEL) | VAF 6/46 reads (13%) | called by mutect2, varscan2
- ZFAT | c.2618G>T p.G873V | Missense Mutation (SNP) | VAF 2/16 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- ZNF84 | c.1070G>T p.S357I | Missense Mutation (SNP) | VAF 10/87 reads (11%) | SIFT tolerated (0.34); PolyPhen possibly damaging (0.768); called by muse, mutect2, varscan2
- ABCB4 | c.42C>A p.P14= | Silent (SNP) | VAF 19/189 reads (10%) | catalogued as COSV55934635; called by muse, mutect2, varscan2
- ACOT12 | c.534A>G p.T178= | Silent (SNP) | VAF 63/574 reads (11%) | catalogued as COSV56894566; called by muse, mutect2, varscan2
- ADAM23 | c.1707T>C p.I569= | Silent (SNP) | VAF 22/509 reads (4%) | catalogued as COSV52214062; called by muse, mutect2
- ADAMTS12 | c.717G>T p.R239= | Silent (SNP) | VAF 23/129 reads (18%) | catalogued as COSV61261793; called by muse, mutect2, varscan2
- ADCY5 | c.2997G>A p.L999= | Silent (SNP) | VAF 12/180 reads (7%) | catalogued as COSV59197131; called by muse, mutect2
- ADGRG4 | c.939T>C p.F313= | Silent (SNP) | VAF 15/147 reads (10%) | catalogued as COSV54954873; called by muse, mutect2, varscan2
- AMER3 | c.1512C>A p.I504= | Silent (SNP) | VAF 6/55 reads (11%) | catalogued as COSV58466430; called by muse, mutect2, varscan2
- ANO4 | c.1893G>A p.R631= (on ENST00000392977 / NM_001286615.2; = p.R596= on NM_178826.4) | Silent (SNP) | VAF 9/120 reads (8%) | catalogued as COSV100152516; called by muse, mutect2
- APOB | c.11518C>T p.L3840= | Silent (SNP) | VAF 13/176 reads (7%) | catalogued as COSV51933748; called by muse, mutect2
- ATP2B2 | c.1620G>A p.K540= (on ENST00000352432; = p.K506= on NM_001683.5) | Silent (SNP) | VAF 9/70 reads (13%) | catalogued as COSV59495288; called by muse, mutect2, varscan2
- BDNF | c.396T>A p.P132= | Silent (SNP) | VAF 9/146 reads (6%) | catalogued as COSV59234863; called by muse, mutect2
- BICRA | c.3306G>T p.T1102= | Silent (SNP) | VAF 10/100 reads (10%) | catalogued as COSV67604611; called by muse, mutect2
- BTBD1 | c.441A>C p.T147= | Silent (SNP) | VAF 13/100 reads (13%) | catalogued as COSV55602838; called by muse, mutect2, varscan2
- C9 | c.210T>C p.F70= | Silent (SNP) | VAF 11/100 reads (11%) | catalogued as COSV54676370; called by muse, mutect2, varscan2
- CDH4 | c.2640C>A p.V880= | Silent (SNP) | VAF 6/62 reads (10%) | catalogued as COSV100848645; called by muse, mutect2
- CDK9 | c.825G>T p.V275= | Silent (SNP) | VAF 8/106 reads (8%) | catalogued as COSV64723703; called by muse, mutect2
- CEACAM3 | c.474C>A p.T158= | Silent (SNP) | VAF 26/304 reads (9%) | catalogued as COSV55761398, COSV55761852; called by muse, mutect2
- CHRNB2 | c.789C>T p.G263= | Silent (SNP) | VAF 19/237 reads (8%) | catalogued as rs202199860, COSV63808080; called by muse, mutect2
- CLCA1 | c.1854C>A p.A618= | Silent (SNP) | VAF 7/57 reads (12%) | catalogued as COSV52327447; called by muse, mutect2
- CNTNAP5 | c.1569G>A p.K523= | Silent (SNP) | VAF 8/114 reads (7%) | catalogued as COSV70483900, COSV70517922; called by muse, mutect2
- COL2A1 | c.4272G>A p.E1424= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as COSV61530015; called by muse, mutect2
- CSMD1 | c.8301G>T p.T2767= (on ENST00000520002; = p.T2766= on NM_033225.6) | Silent (SNP) | VAF 15/140 reads (11%) | catalogued as rs765938760, COSV59315997, COSV59328648, COSV59361465; called by muse, mutect2, varscan2
- DCAF12L1 | c.1290G>C p.A430= | Silent (SNP) | VAF 34/336 reads (10%) | catalogued as rs755096870, COSV64421685; called by muse, mutect2
- DCAF4L2 | c.855G>C p.L285= | Silent (SNP) | VAF 11/98 reads (11%) | catalogued as COSV60478246; called by muse, mutect2, varscan2
- DDX54 | c.706C>T p.L236= | Silent (SNP) | VAF 15/301 reads (5%) | catalogued as COSV58373200; called by muse, mutect2
- DPYS | c.699C>A p.A233= | Silent (SNP) | VAF 10/85 reads (12%) | catalogued as COSV60908232; called by muse, mutect2, varscan2
- ERBB3 | c.105C>G p.G35= | Silent (SNP) | VAF 18/360 reads (5%) | catalogued as COSV57252065; called by muse, mutect2
- FRAS1 | c.2601C>T p.C867= | Silent (SNP) | VAF 4/40 reads (10%) | catalogued as COSV53606705; called by muse, mutect2
- GABRB3 | c.594G>A p.K198= | Silent (SNP) | VAF 25/157 reads (16%) | catalogued as rs1381956789, COSV54661785; called by muse, mutect2, varscan2
- GOLPH3 | c.255A>T p.I85= | Silent (SNP) | VAF 9/96 reads (9%) | catalogued as COSV54059621, COSV54060568; called by muse, mutect2
- GPR150 | c.186A>T p.T62= | Silent (SNP) | VAF 5/21 reads (24%) | catalogued as COSV66168288; called by muse, mutect2, varscan2
- GPR61 | c.678G>T p.V226= | Silent (SNP) | VAF 22/342 reads (6%) | catalogued as COSV63983675; called by muse, mutect2
- HELB | c.2587C>T p.L863= | Silent (SNP) | VAF 8/119 reads (7%) | catalogued as COSV56073541; called by muse, mutect2
- HGF | c.834C>A p.T278= | Silent (SNP) | VAF 12/138 reads (9%) | catalogued as COSV55948073; called by muse, mutect2
- IFNGR2 | c.471C>T p.I157= | Silent (SNP) | VAF 44/468 reads (9%) | catalogued as COSV51639209, COSV99274728; called by muse, mutect2
- IFT172 | c.1134G>T p.L378= | Silent (SNP) | VAF 45/365 reads (12%) | catalogued as rs748753565, COSV53133107; called by muse, mutect2, varscan2
- KCNA10 | c.1185T>C p.F395= | Silent (SNP) | VAF 4/79 reads (5%) | catalogued as COSV63904605; called by muse, mutect2
- KRT6B | c.468C>T p.I156= | Silent (SNP) | VAF 15/273 reads (5%) | catalogued as COSV52881796; called by muse, mutect2
- LAMA4 | c.2475C>A p.T825= (on ENST00000230538 / NM_001105206.3; = p.T818= on NM_002290.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 20/184 reads (11%) | catalogued as COSV57895916; called by muse, mutect2, varscan2
- LDB3 | c.681C>A p.L227= | Silent (SNP) | VAF 16/205 reads (8%) | catalogued as COSV53940676; called by muse, mutect2
- LRP1B | c.6234G>T p.V2078= | Silent (SNP) | VAF 20/298 reads (7%) | catalogued as COSV67211954; called by muse, mutect2
- LRRC7 | c.1776C>A p.P592= (on ENST00000651989 / NM_001370785.2; = p.P559= on NM_001330635.3 and 2 other RefSeq transcripts) | Silent (SNP) | VAF 26/308 reads (8%) | catalogued as COSV50448194; called by muse, mutect2
- MAEL | c.1032G>T p.G344= | Silent (SNP) | VAF 15/173 reads (9%) | catalogued as COSV100901775; called by muse, mutect2
- MAP1A | c.2316A>G p.T772= | Silent (SNP) | VAF 8/49 reads (16%) | catalogued as COSV55808125; called by muse, mutect2, varscan2
- MARCHF4 | c.1201C>A p.R401= | Silent (SNP) | VAF 32/205 reads (16%) | catalogued as COSV56104742, COSV56108849; called by muse, mutect2, varscan2
- MCM10 | c.1425A>T p.A475= (on ENST00000484800 / NM_182751.3; = p.A474= on NM_018518.5) | Silent (SNP) | VAF 7/95 reads (7%) | catalogued as COSV66334128; called by muse, mutect2
- MUC16 | c.41838C>G p.S13946= | Silent (SNP) | VAF 7/103 reads (7%) | catalogued as COSV66691567; called by muse, mutect2
- MUC16 | c.30891C>A p.A10297= | Silent (SNP) | VAF 14/200 reads (7%) | catalogued as COSV67462387; called by muse, mutect2
- MUC16 | c.16776G>T p.G5592= | Silent (SNP) | VAF 15/188 reads (8%) | catalogued as COSV67462399, COSV67482886; called by muse, mutect2
- MYH2 | c.5791C>A p.R1931= | Silent (SNP) | VAF 38/314 reads (12%) | catalogued as COSV55436866; called by muse, mutect2, varscan2
- NDST4 | c.906G>A p.R302= | Silent (SNP) | VAF 13/173 reads (8%) | catalogued as rs1328532268, COSV52117684; called by muse, mutect2
- NPAP1 | c.1242C>G p.T414= | Silent (SNP) | VAF 11/124 reads (9%) | catalogued as COSV61506415; called by muse, mutect2
- NTSR1 | c.345C>A p.T115= | Silent (SNP) | VAF 13/111 reads (12%) | catalogued as COSV65138463; called by muse, mutect2
- OGT | c.585T>C p.S195= | Silent (SNP) | VAF 16/242 reads (7%) | catalogued as COSV101035548, COSV65480605; called by muse, mutect2
- OR13G1 | c.858G>T p.V286= | Silent (SNP) | VAF 20/228 reads (9%) | catalogued as COSV100686996, COSV62944021; called by muse, mutect2
- OR1M1 | c.801C>A p.T267= | Silent (SNP) | VAF 21/234 reads (9%) | catalogued as COSV70036824; called by muse, mutect2
- OR4C16 | c.438C>A p.A146= | Silent (SNP) | VAF 17/206 reads (8%) | catalogued as COSV58941747; called by muse, mutect2
- ORC1 | c.2046A>T p.T682= | Silent (SNP) | VAF 19/171 reads (11%) | catalogued as COSV65363780; called by muse, mutect2, varscan2
- PCDHGA4 | c.2376G>C p.A792= | Silent (SNP) | VAF 38/313 reads (12%) | catalogued as COSV53937267; called by muse, mutect2, varscan2
- PPIP5K2 | c.3186C>G p.G1062= | Silent (SNP) | VAF 5/48 reads (10%) | catalogued as COSV58605229; called by muse, mutect2
- PSG9 | c.165C>A p.V55= | Silent (SNP) | VAF 43/352 reads (12%) | catalogued as COSV52484740; called by muse, mutect2, varscan2
- PTPRN2 | c.1485C>G p.L495= | Silent (SNP) | VAF 12/128 reads (9%) | catalogued as COSV67034988; called by muse, mutect2
- RP1 | c.582T>A p.P194= | Silent (SNP) | VAF 24/406 reads (6%) | catalogued as COSV55115615; called by muse, mutect2
- RP1L1 | c.1296C>G p.V432= | Silent (SNP) | VAF 14/152 reads (9%) | catalogued as COSV66754458; called by muse, mutect2
- RUFY4 | c.1566G>T p.V522= | Silent (SNP) | VAF 7/67 reads (10%) | catalogued as COSV100723000; called by muse, mutect2, varscan2
- SALL1 | c.573C>A p.I191= | Silent (SNP) | VAF 9/142 reads (6%) | catalogued as COSV51756670; called by muse, mutect2
- SEC22A | c.477G>T p.G159= | Silent (SNP) | VAF 22/303 reads (7%) | catalogued as COSV59371860, COSV59372351; called by muse, mutect2
- SEMA5A | c.984G>T p.A328= | Silent (SNP) | VAF 27/202 reads (13%) | catalogued as rs1806117, COSV66791259, COSV66798891; called by muse, mutect2, varscan2
- SLBP | c.234A>T p.A78= | Silent (SNP) | VAF 23/245 reads (9%) | catalogued as COSV59183778; called by muse, mutect2
- SLC17A1 | c.663T>C p.Y221= | Silent (SNP) | VAF 18/93 reads (19%) | catalogued as COSV55078597; called by muse, mutect2, varscan2
- SLC5A4 | c.1233C>T p.T411= | Silent (SNP) | VAF 24/234 reads (10%) | catalogued as COSV56669990; called by muse, mutect2, varscan2
- SLCO1A2 | c.1092T>A p.P364= | Silent (SNP) | VAF 6/46 reads (13%) | catalogued as COSV56601183; called by muse, mutect2
- STAB2 | c.4146C>A p.A1382= | Silent (SNP) | VAF 6/90 reads (7%) | catalogued as COSV66338316; called by muse, mutect2
- STAM | c.1596A>G p.Q532= | Silent (SNP) | VAF 12/364 reads (3%) | catalogued as COSV66351404; called by muse, mutect2
- STKLD1 | c.156C>A p.V52= | Silent (SNP) | VAF 8/94 reads (9%) | catalogued as COSV64312442; called by muse, mutect2
- SUCLG1 | c.459A>G p.V153= | Silent (SNP) | VAF 16/161 reads (10%) | catalogued as COSV67265081; called by muse, mutect2, varscan2
- TAS2R30 | c.741A>T p.I247= | Silent (SNP) | VAF 12/183 reads (7%) | catalogued as COSV67855365; called by muse, mutect2
- TBX15 | c.828G>C p.V276= (on ENST00000369429 / NM_001330677.2; = p.V170= on NM_152380.3) | Silent (SNP) | VAF 5/65 reads (8%) | catalogued as COSV52870735; called by muse, mutect2
- TCP11 | c.1266C>T p.V422= (on ENST00000512012; = p.V360= on NM_018679.5) | Silent (SNP) | VAF 19/403 reads (5%) | catalogued as COSV55133485; called by muse, mutect2
- THSD1 | c.1581G>A p.L527= | Silent (SNP) | VAF 17/282 reads (6%) | catalogued as COSV51628100; called by muse, mutect2
- TIE1 | c.1851G>A p.Q617= | Silent (SNP) | VAF 13/148 reads (9%) | catalogued as rs759140998, COSV65249519; called by muse, mutect2
- TMEM200A | c.132C>A p.P44= | Silent (SNP) | VAF 14/253 reads (6%) | catalogued as COSV99758981; called by muse, mutect2
- TMEM215 | c.4C>A p.R2= | Silent (SNP) | VAF 28/144 reads (19%) | catalogued as rs765736341, COSV61363397, COSV61364093; called by muse, mutect2
- TMEM39B | c.582C>G p.L194= | Silent (SNP) | VAF 14/147 reads (10%) | catalogued as COSV60378768; called by muse, mutect2, varscan2
- TRIM22 | c.756G>T p.V252= | Silent (SNP) | VAF 13/144 reads (9%) | catalogued as COSV66090733; called by muse, mutect2
- TTN | c.59127C>A p.V19709= (on ENST00000591111; = p.V12285= on NM_003319.4) | Silent (SNP) | VAF 22/398 reads (6%) | catalogued as COSV60017579; called by muse, mutect2
- TTYH1 | c.360C>G p.S120= | Silent (SNP) | VAF 20/175 reads (11%) | catalogued as COSV56611376; called by muse, mutect2, varscan2
- TUT7 | c.1317A>G p.A439= | Silent (SNP) | VAF 10/142 reads (7%) | catalogued as COSV52895372; called by muse, mutect2
- USH2A | c.11793C>G p.T3931= | Silent (SNP) | VAF 16/148 reads (11%) | catalogued as COSV100232351; called by muse, mutect2
- WDR86 | c.402G>T p.R134= | Silent (SNP) | VAF 8/83 reads (10%) | catalogued as COSV100561224; called by muse, mutect2
- XPO6 | c.1242C>T p.Y414= | Silent (SNP) | VAF 17/116 reads (15%) | catalogued as COSV58965968; called by muse, mutect2, varscan2
- XYLT1 | c.2583G>T p.G861= | Silent (SNP) | VAF 20/141 reads (14%) | catalogued as COSV54483148; called by muse, mutect2, varscan2
- AL353804.7 | chrX:73846176 C>A | 5'Flank (SNP) | VAF 18/230 reads (8%) | catalogued as rs879206476; called by muse, mutect2
- BMP1 | c.731-266G>A | Intron (SNP) | VAF 30/344 reads (9%) | catalogued as COSV100109335; called by muse, mutect2
- KLK8 | c.71-19C>T | Intron (SNP) | VAF 8/154 reads (5%) | catalogued as COSV99143931; called by muse, mutect2
- NXF5 | n.1360G>T | RNA (SNP) | VAF 16/257 reads (6%) | catalogued as COSV53790675, COSV99534399; called by muse, mutect2
